Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VW, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VW-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Report Status: Final

ICD O-3

Procedure Date:

Mesothelioma, liphasic, malignant
Site: Pleura NOS 9053/3
C38.4
JW6/13/14

PATHOLOGIC DIAGNOSIS:

- A. SKIN, OLD INCISION, EXCISION:
Skin and subcutis with scar, negative for tumor.
- B. RIB:
Bone marrow with maturing trilineage hematopoiesis, negative for tumor.
- C. RIGHT CHEST WALL MASS:
MALIGNANT MESOTHELIOMA (0.7 cm), predominantly sarcomatoid type,
involving fibroadipose tissue.
Adjacent fibroadipose tissue with foreign body giant cell reaction.
- D. RIGHT CHEST WALL MASS (INCLUDING FSA):
MALIGNANT MESOTHELIOMA (2.0 cm), mixed epithelial and sarcomatoid type,
involving skeletal muscle and fibroadipose tissue.
- E. ADDITIONAL RIGHT CHEST WALL MASS:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type,
involving skeletal muscle.
- F. RIGHT PLEURA:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type,
involving fibroadipose tissue.
- G. CHEST WALL RESECTION:
MALIGNANT MESOTHELIOMA, multiple nodules (up to 5.5 cm), mixed
epithelial and sarcomatoid type.
Tumor invades into fibroadipose tissue, skeletal muscle, and bone.
Tumor abuts and focally invades lung parenchyma.
Tumor necrosis is present.
Tumor is present at the superior, inferior, lateral, medial, chest wall,
and pleural soft tissue margins.
Tumor is present at the medial and lateral bony resection margins.
- H. ADDITIONAL TUMOR:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type, with
extensive necrosis.
- I. RIGHT PLEURA:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type, involving
fibroadipose tissue and skeletal muscle.
Tumor abuts and focally invades lung parenchyma.
- J. RIB:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type,
involving periosteal fibroadipose tissue.
Bone marrow with maturing trilineage hematopoiesis.
- K. PARATRACHEAL LYMPH NODE:
One (1) lymph node, negative for tumor.
- L. PERICARDIAC TUMOR:
MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type, involving

[page 2 of 4]
Pathology Report

fibroadipose tissue.

M. VISCERAL PLEURA:

MALIGNANT MESOTHELIOMA, mixed epithelial and sarcomatoid type, involving fibroadipose tissue.

Tumor abuts and focally invades lung parenchyma.

TISSUE SUBMITTED:

- A/1) Old incision.
- B/2) Rib
- C/3) Rt chest wall mass.
- D/4) Rt chest wall mass (FS).
- E/5) Rt chest wall mass for () FS.
- F/6) Rt pleura () FS.
- G/7) Chest wall - long - lateral spine, short - medial spine.
- H/8) (FS).
- I/9) Rt pleura.
- J/10) Rib
- K/11) Paratracheal lymph node.
- L/12) Pericardiac tumor.
- M/13) Visceral pleura.

O.R. CONSULTATION:

SPECIMEN LABELED "#4. RT CHEST WALL MASS" (FSA):

Spindle-cell malignant neoplasm, consistent with mesothelioma.

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnos(es) related thereto.

GROSS DESCRIPTION:

The specimen was received fresh, in thirteen parts, and each labeled with the patient's name and unit number.

Part A, specimen labeled "#1. Old incision", consists of a 21.5 x 0.5 cm skin excision with an excision depth of 1.1 cm. The specimen was inked blue and serially sectioned. No masses or lesions were seen.

Micro A1: Sections of skin, 5 frags, RSS.

Part B, specimen labeled "#2. Rib", consists of a fragment of rib 11.7 cm in length. No masses or lesions were identified. A successful bone marrow squeeze was performed.

Micro B1: Rib bone marrow, multi frags, RSS.

Part C, specimen labeled "#3. Right chest wall mass", consists of a 1.6 x 0.9 x 0.6 cm red/tan/yellow soft tissue with a firm, tan (0.7 cm in greatest dimension) nodule.

Micro C1: Soft tissue fragment, bisected, 2 frags, ESS.

Part D, specimen labeled "#4. Right chest wall mass", consists of a 3.0 x 2.0 x 1.0 cm soft tissue fragment, which contains a 2.0 x 1.0 x 0.5 cm firm white nodule. The specimen was bisected and one half of the nodule was submitted as FSA and the other half of the nodule was submitted to

[page 3 of 4]
Pathology Report

Micro D1: FSA remnant, 1 frag, ESS.

Micro D2: Non-frozen FSA remnant, 1 frag, ESS.

Part E, specimen labeled "#5. Right chest wall mass for _____ consists of a 2.8 x 1.8 x 0.7 cm tan/white nodular soft tissue fragment with adherent tan/red muscular soft tissue. A representative section of the sample was submitted to

Micro E1: Remaining soft tissue, 2 frags, ESS.

Part F, specimen labeled "#6. Right pleura for _____ consists of a 5.0 x 4.0 x 1.2 cm aggregate of tan/pink nodular soft tissue fragment. A representative sample (60%) was divided and sent to

Micro F1-F2: Sections of soft tissue, 1 and 2 frags respectively, RSS.

Part G, specimen labeled "#7. Chest wall", consists of a chest wall resection, measuring 13.6 cm superior to inferior, 11.5 cm medial to lateral, and 13.5 cm anterior to posterior. The specimen was oriented by the surgeon as long stitch equals lateral spine, short stitch equals medial spine, and Vicryl equals superior. The specimen was inked as red equals superior, green equals inferior, black equals pleural surface, blue equals chest wall surface, yellow equals lateral spine, and orange equals medial spine. The resection includes three ribs (9.0, 8.7, and 8.8 cm in length). The superior most rib is fractured. The pleural surface is relatively smooth and nodular. The largest aggregate of nodules is 5.5 cm in greatest dimension. Grossly, the nodules are abutting the chest wall resection edge, less than 0.1 cm/abutting the pleural surface, less than 0.1 cm from the superior resection margin, abutting the inferior resection margin, abutting the medial resection margin, and less than 0.1 cm from the lateral resection margin. The middle rib on the medial side only contained a small amount of bone protruding to the resection surface. The lower most rib on the medial side did not extend all the way to the medial soft tissue resection edge and protruded out more towards the chest wall side. The tumor appears to grossly invade all three ribs.

Micro G1: Medial bone resection margin of the upper most rib, 1 frag, en face, ESS.

Micro G2: Medial bone resection margin of the middle rib, en face, 4 frags, ESS.

Micro G3: Medial bone resection margin of the lower most rib, on chest wall surface, en face, 1 frag, ESS.

Micro G4: Lateral bone resection margin of upper most rib, en face, 1 frag, ESS.

Micro G5: Lateral bone resection margin of the middle rib, en face, 3 frags, ESS.

Micro G6: Lateral bone resection margin of lower most rib, en face, 1 frag, ESS.

Micro G7: Tumor to bone, 1 frag, RSS.

Micro G8: Superior margin, perpendicular, 1 frag, RSS.

Micro G9: Tumor to pleural and chest wall surfaces, 1 frag, RSS.

Micro G10: Tumor to inferior resection margin, perpendicular, 1 frag, RSS.

Micro G11: Tumor to lateral soft tissue resection margin, perpendicular, RSS.

Micro G12: Tumor to medial soft tissue resection margin, perpendicular, 1 frag, RSS.

Part H, specimen labeled "#8. _____ consists of a 5.6 x 4.4 x 3.9 cm tan/red nodule with a partially smooth and partially disrupted surface. The outer surface was inked black. The specimen was sectioned to reveal a tan cut surface.

Micro H1-H2: Sections of nodule, 1 frag each, RSS.

Part I, specimen labeled "#9. Right pleura", consists of a 210-gram (16.7 x 13.8 x 5.2 cm) aggregate of tan, firm soft tissue (tumor) with attached pleura and fibroadipose tissue. The largest single nodule of tumor measures 4.1 x 3.9 x 3.5 cm.

[page 4 of 4]
Pathology Report

Micro I1-I4: Sections of tumor, multi frags, RSS.

Part J, specimen labeled "#10. Rib", consists of a 6.7 cm in length fragment of rib with attached skeletal muscle and nodules of tumor, 2.3 cm in greatest dimension. A successful bone marrow squeeze was performed.

Micro J1: Bone marrow, multi frags, RSS.

Micro J2: Tumor to bone, 2 frags, RSS.

Part K, specimen labeled "#11. Paratracheal lymph node", consists of a 3.0 x 2.1 x 0.3 cm aggregate of yellow/red soft tissue, which contains a 1.0 x 0.7 x 0.3 cm black/red lymph node candidate.

Micro K1: Lymph node candidate and soft tissue, 2 frags, ESS.

Part L, specimen labeled "#12. Pericardial tumor", consists of a 7.4 x 4.0 x 2.1 cm fragment of fibromembranous tissue with two to three firm tan nodules (3.5 cm in greatest dimension).

Micro L1-L2: Sections of fibromembranous tissue and nodule, 1 and 2 frags respectively, RSS.

Part M, specimen labeled "#13. Visceral pleura", consists of a 16.7 x 13.4 x 3.1 cm aggregate of red/tan fibromembranous tissue with attached firm tan nodules (5.1 cm in greatest dimension). There is also scant attached skeletal muscle and adipose tissue.

Micro M1-M4: Sections of tumor and associated tissue, multi frags, RSS.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file 9867a4c2-77af-4626-bbd2-fdccdbb88efb (TCGA-ZN-A9VW.C3231F34-1580-4BBC-ABEF-BF2693249E3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).